CCDI case PBCLFH — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Lymph nodes.
https://portal.gdc.cancer.gov/cases/001f2cb6-1e40-4f13-b223-adaa355a08e3

Demographics
Sex at birth: male; Race: black or african american.

Diagnoses (1)
1. Carcinoma, metastatic, NOS: ICD-O-3 morphology code: 8010/6; Tissue or organ of origin: Lymph nodes of inguinal region or leg; Age at diagnosis: 12.0 years (4,385 days).

Biospecimens (3 samples)
- Sample 0DUETP: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Samples 0DUEUA, 0DUEUE (2 with the same recorded description): Tissue type: Tumor; Specimen type: Solid Tissue.
